Somatic mutation profile of tumor specimen C3N-03935-01 (aliquot CPT0285340006) from CPTAC case C3N-03935, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 29.8 years (10,894 days).
Specimen C3N-03935-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daf63185-70e4-4ccf-b73b-c8e8a98ef5c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03935-31 (Blood Derived Normal), aliquot CPT0285370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da4b2d33-ef91-46a9-a264-53ff663aedbb

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, RNA 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 378/631 reads (60%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 1911/2218 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- TP53 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 258/302 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 63/137 reads (46%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- KANK2 | c.2483G>A p.R828H (on ENST00000586659 / NM_001379562.1; = p.R836H on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200363050, COSV62007688; called by muse, mutect2, varscan2
- LMTK2 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs145315793, COSV99806615; called by muse, mutect2, varscan2
- MAP4K1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 221/347 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745816882, COSV101204466; called by muse, mutect2, varscan2
- PPM1D | c.1451T>A p.L484* | Nonsense Mutation (SNP) | VAF 96/215 reads (45%) | catalogued as CD132017, CM131997, COSV100010613, COSV59954652, COSV59957436; called by muse, mutect2, varscan2
- RAD18 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as rs187913630; called by muse, mutect2, varscan2
- RYR3 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV101212767; called by muse, mutect2, varscan2
- ARAP2 | c.2442+1G>A p.X814_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.2879G>A p.G960E | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ATAD3C | c.378G>A p.Q126= | Splice Region (SNP) | VAF 164/346 reads (47%) | called by muse, mutect2, varscan2
- DDX58 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIAA2012 | c.13_24del p.S5_S8del | In Frame Del (DEL) | VAF 42/150 reads (28%) | called by mutect2, pindel, varscan2
- RAB33A | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 233/581 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- STUM | c.241del p.R81Afs*15 | Frame Shift Del (DEL) | VAF 152/312 reads (49%) | called by mutect2, pindel, varscan2
- SUV39H1 | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- WDR81 | c.3328G>T p.D1110Y (on ENST00000409644 / NM_001163809.2; = p.D59Y on NM_152348.4) | Missense Mutation (SNP) | VAF 81/141 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ATAD5 | c.156G>A p.R52= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs1357378772, COSV58976864; called by muse, varscan2
- C1R | c.1797C>T p.Y599= (on ENST00000536053 / NM_001354346.2; = p.Y585= on NM_001733.7) | Silent (SNP) | VAF 58/168 reads (35%) | catalogued as rs779060240, COSV73383051; called by muse, mutect2, varscan2
- CHRNE | c.1239G>A p.L413= | Silent (SNP) | VAF 155/343 reads (45%) | called by muse, mutect2, varscan2
- MAN2C1 | c.1851G>T p.G617= | Silent (SNP) | VAF 131/297 reads (44%) | called by muse, mutect2, varscan2
- MAST4 | c.2554C>T p.L852= (on ENST00000403625 / NM_001164664.2; = p.L663= on NM_015183.3) | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2
- MAST4 | c.2556G>C p.L852= (on ENST00000403625 / NM_001164664.2; = p.L663= on NM_015183.3) | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2
- SPTA1 | c.6675C>T p.D2225= | Silent (SNP) | VAF 141/483 reads (29%) | catalogued as rs186647435, COSV63749286; called by muse, mutect2, varscan2
- TCF4 | c.240G>A p.T80= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1185734703, COSV68173842; called by muse, mutect2, varscan2
- AC008758.3 | n.683T>C | RNA (SNP) | VAF 79/191 reads (41%) | called by muse, mutect2, varscan2
- C8orf86 | n.609A>T | RNA (SNP) | VAF 229/547 reads (42%) | called by muse, mutect2, varscan2
- NECTIN2 | c.1043-3845G>A | Intron (SNP) | VAF 234/373 reads (63%) | called by muse, mutect2, varscan2
- PRRT1 | c.*219G>A | 3'UTR (SNP) | VAF 76/159 reads (48%) | catalogued as rs779350473; called by muse, mutect2, varscan2
